Gene-level copy-number profile of tumor specimen SM-JU33E from CPTAC case C266664, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS.
Specimen SM-JU33E: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Cerebrum; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f4db0400-8f19-4f86-89db-ca093872c893.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator 1105287 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,724 have no estimate.
https://portal.gdc.cancer.gov/files/fcc5d6d8-df87-4ad6-a9fe-f6258f722592

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 560; copy number 1: 132; copy number 2: 17,652; copy number 3: 21,696; copy number 4: 15,897; copy number 5: 1,353; copy number 6: 1,199; copy number 7: 235; copy number 8: 87; copy number 9: 48; copy number 10: 28; copy number 11: 9; copy number 13: 3.

Homozygous deletions (total copy number 0; autosomes only): 48 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:61,581,813–61,662,690, 4 genes: AL935212.3, FAM242D, Y_RNA, AL935212.1.
- chr15:30,150,872–30,625,773, 31 genes (within-gene range 0–2): DNM1P30, AC120045.2, AC120045.1, LINC02249, AC135731.1, RNU6-17P, AC135731.2, AC019322.4, Y_RNA, CHRFAM7A, AC019322.1, U8, AC019322.3, GOLGA8R, RN7SL196P, AC019322.2, AC127502.1, AC127502.2, AC127502.3, AC026150.2, AC026150.1, GOLGA8Q, RN7SL796P, DNM1P50, ULK4P2, U8, GOLGA8H, AC026150.3, RN7SL628P, AC091057.3, AC091057.2.
- chr15:63,042,632–63,071,915, 3 genes: TPM1, TPM1-AS, AC079328.2.
- chr18:46,917,492–47,102,243, 8 genes (within-gene range 0–3): KATNAL2, ELOA3D, ELOA3C, ELOA3B, ELOA3, ELOA2, AC012254.5, AC012254.1.
- chr18:78,976,555–79,002,677, 2 genes: LINC01896, SALL3.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 410 genes in 21 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,702,736–1,891,117, 5 genes, copy number 7 (within-gene range 5–7): AL031282.2, AL031282.1, SLC35E2A, NADK, GNB1.
- chr1:6,101,787–6,393,767, 10 genes, copy number 7 (within-gene range 5–7): CHD5, AL031847.1, RPL22, RNF207-AS1, RNF207, ICMT, LINC00337, HES3, GPR153, ACOT7.
- chr2:85,394,753–85,442,791, 5 genes, copy number 7: CAPG, AC062037.3, SH2D6, Y_RNA, RN7SL251P.
- chr3:6,770,001–7,741,533, 1 gene, copy number 8 (within-gene range 2–8): GRM7.
- chr3:6,892,632–8,963,773, 17 genes, copy number 8–10: GRM7-AS2, AC066585.1, GRM7-AS1, AC077690.1, LMCD1-AS1, AC018832.1, AC023481.1, RNU4ATAC17P, LMCD1, AC034187.1, SSUH2, OR7E122P, CAV3, OXTR, RAD18, AC034186.2, AC034186.1.
- chr3:12,257,801–15,053,600, 55 genes, copy number 9–13 (within-gene range 6–13): GSTM5P1, PPARG, AC091492.1, TSEN2, RNA5SP123, RNU6-377P, MKRN2OS, MKRN2, Metazoa_SRP, RAF1, CRIP1P1, TMEM40, KRT18P17, CAND2, AC034198.2, RPL32, SNORA7A, AC034198.1, LINC02022, IQSEC1, AC069271.1, NUP210, AC027124.2, AC027124.1, HDAC11-AS1, HDAC11, FBLN2, LINC00620, WNT7A, VN1R20P, FGD5P1, TPRXL, AC090004.2, VN1R21P, CHCHD4, TMEM43, AC090004.1, XPC-AS1, XPC, LSM3, AC093496.1, LINC01267, RNA5SP124, SLC6A6, GRIP2, RNU6-905P, RHBDF1P1, AC090952.1, CCDC174, C3orf20, AC090957.1, LINC02011, FGD5, FGD5-AS1, NR2C2.
- chr3:19,148,510–25,873,748, 66 genes, copy number 7–9 (broad region; genes not listed).
- chr5:1,201,595–2,119,926, 32 genes, copy number 8: SLC6A19, SLC6A18, AC114291.1, TERT, MIR4457, CLPTM1L, LINC01511, MTCO2P32, AC026748.3, SLC6A3, LPCAT1, MIR6075, AC091849.2, SDHAP3, AC026412.3, AC091849.1, AC026412.1, AC026412.2, MIR4277, AC112176.1, MRPL36, NDUFS6, AC025183.1, LINC02116, AC025183.2, IRX4, IRX4-AS1, CTD-2194D22.4, AC126768.3, AC124852.1, AC126768.1, AC126768.2.
- chr5:6,289,857–8,157,788, 36 genes, copy number 7: HMGB3P3, LINC02145, MED10, UBE2QL1, AC027334.1, LINC01018, NSUN2, SRD5A1, LINC02102, TENT4A, LINC02236, AC122710.2, LINC02196, RN7SKP79, AC122710.1, RNA5SP176, AC025756.1, Metazoa_SRP, AC091951.2, AC091951.3, AC091951.1, AC027343.3, LINC02123, AC027343.1, AC027343.2, LINC02142, ADCY2, AC093305.1, C5orf49, MTRR, FASTKD3, AC025174.1, RNU1-76P, AC091941.1, AC091912.2, AC091912.1.
- chr5:10,057,502–10,138,365, 5 genes, copy number 8: AC091905.2, AC091905.3, AC091905.1, AC091905.4, AC034229.1.
- chr5:39,105,252–44,066,731, 81 genes, copy number 7 (broad region; genes not listed).
- chr8:17,469,518–17,800,917, 10 genes, copy number 10 (within-gene range 6–11): ADAM24P, SLC7A2, AP006248.2, AP006248.4, SLC7A2-IT1, AP006248.3, PDGFRL, AP006248.1, AP006248.5, MTUS1.
- chr8:17,748,118–18,223,689, 12 genes, copy number 7–11: RNA5SP256, AC027117.2, AC027117.1, FGL1, AC087273.1, AC087273.2, PCM1, ASAH1, AC124242.1, AC124242.2, NAT1, MTND4LP26.
- chr13:74,231,457–74,259,976, 1 gene, copy number 8: LINC00402.
- chr13:76,134,931–76,135,225, 1 gene, copy number 8: RN7SL571P.
- chr14:21,070,273–21,565,084, 26 genes, copy number 7 (within-gene range 4–7): ARHGEF40, ZNF219, TMEM253, AL161668.1, CKAP2P1, RNU6-252P, OR5AU1, SMARCE1P3, AL157687.1, LINC00641, HNRNPC, RPGRIP1, SUPT16H, AL135744.1, CHD8, SNORD9, SNORD8, AL161747.1, EIF4EBP1P1, RN7SL650P, RAB2B, TOX4, METTL3, SALL2, AL161747.2, RBBP4P5.
- chr14:21,712,321–21,783,503, 8 genes, copy number 7: TRAV2, AC243972.1, TRAV3, TRAV4, TRAV5, RPL4P1, TRAV6, TRAV7.
- chr17:22,056,587–22,439,033, 12 genes, copy number 7: ABBA01006766.1, NCOR1P2, UBBP4, FTLP13, LINC02002, AC138761.1, AC138761.2, FAM27E5, AC087575.1, FLJ36000, AC132825.3, AC132825.4.
- chr17:48,929,316–49,056,145, 11 genes, copy number 7 (within-gene range 4–7): SNF8, AC091133.1, RNU1-42P, AC091133.2, GIP, AC091133.3, IGF2BP1, AC091133.4, Metazoa_SRP, RNU6-826P, AC091133.5.
- chr17:77,014,880–77,500,596, 13 genes, copy number 8 (within-gene range 2–8): Metazoa_SRP, SNHG20, SEC14L1, SCARNA16, MIR6516, RNU4-47P, CYCSP40, SEPTIN9-DT, AC068594.1, SEPTIN9, AC111182.1, AC111182.2, MIR4316.
- chr19:43,192,702–43,269,530, 3 genes, copy number 8: PSG4, CEACAMP10, PSG9.

Autosomal genes at a single copy (total copy number 1): 124. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
